Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A8I0, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A8I0-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Clinical Case Report

(For Collection of Cancerous Tissue)

ICD O-3
Carcinoma, squamous cell NOS
Site Esophagus, distal third
867613
015.5
8/11/26/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	VIETNAMESE	
☒ Male ☐ Female		☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			127/8	

HISTORY OF PRESENT ILLNESS

Chief Complaints: Trouble swallowing, cough

Symptoms: Weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1/2 p / day	30 (yrs)	Still Smoke (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		1 drink / day	25 (yrs)	4 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers: _____						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the oesophagus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Esophageal cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: II A		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the upper part of oesophagus			
Primary Tumor			
Organ	Detailed Location	Size	
Esophageal tumor	Lower third	5 x 3 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T2 N0 M0 Stage: II A			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
ESOPHAGUS TUMOR	5 x 3 x 1 cm	Lower Third	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: II A	
Notes: Lympho nodes 2 (Negative 2)			

[page 5 of 5]
IRB APPROVED

Consolidated Pathology Diagnosis

Cell Distribution			Structural Pattern		
	+	-		+	-
Diffuse		✓	Streaming		
Mosaic	✓		Storiform		
Necrosis		✓	Fibrosis		
Lymphocytic Infiltration	✓		Palisading		
Vascular Invasion		✓	Cystic Degeneration		
Clusterized	✓		Bleeding		
Alveolar Formation		✓	Myxoid Change		
Indian File		✓	Psammoma/Calcification		

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	✓		Glandular cell			Round Cell			Large Cell		
Spindle Cell	✓		Cell Stratification			Fibroblast			Small Cell		
Keratin	✓		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	✓		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl	✓		Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☐ Moderate ☐ Poor

Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			✓	
Hyperchromatism			✓	
Nucleolar Prominent			✓	
Multinucleated Giant Cell			✓	
Mitotic Activity			✓	

Nuclear Grade: ☒ 0 ☐ I ☐ II ☐ III

D1 70% D2 70% D3 70% D4 75%

Final Pathology Report

Histological Diagnosis: Squamous Cell Carcinoma Grade: 2

Comments:

H1, H2: Chronic Lymphocytic

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS - FOR

Primary Tumor Discrepancy		✓
HIFAA Discrepancy		✓
Case is (check):		

Source: NCI Genomic Data Commons file a4aebe2c-856a-4421-a2c6-27ed551d55bd (TCGA-LN-A8I0.9FBEBA35-BD49-4F4C-9B7F-56341EBFC5C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).